Somatic mutation profile of tumor specimen 0DW2W6 from CCDI case PBCMWC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Posterior mediastinum; Age at diagnosis: 6.5 years (2,388 days).
Specimen 0DW2W6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de4db7e9-5624-4f6c-b0be-ec1c477f02b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW2VL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/907aa618-554d-4d3d-90b6-31f87b058408

The open-access MAF lists 50 somatic variants for this specimen: 33 protein-altering or splice-affecting, 8 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 8, Intron 6, Splice Site 2, Splice Region 2, 3'UTR 2, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APCDD1 | c.299A>G p.N100S | Missense Mutation (SNP) | VAF 152/356 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.279); catalogued as rs1255479618; called by muse, mutect2, varscan2
- ARFGEF3 | c.2750G>A p.G917E | Missense Mutation (SNP) | VAF 107/482 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52459029; called by muse, mutect2, varscan2
- BCL9L | c.749+1G>A p.X250_splice | Splice Site (SNP) | VAF 45/96 reads (47%) | catalogued as rs1484630667; called by muse, mutect2, varscan2
- CDH3 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 55/232 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50558998; called by muse, mutect2
- FAM71E2 | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.535); catalogued as rs773703321; called by muse, mutect2, varscan2
- NCOA3 | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372533478; called by muse, mutect2, varscan2
- OR10V1 | c.27G>T p.K9N | Missense Mutation (SNP) | VAF 81/181 reads (45%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs756234162, COSV55697893; called by muse, mutect2, varscan2
- OTOF | c.3346C>T p.R1116* (on ENST00000272371 / NM_194248.3; = p.R369* on NM_004802.4) | Nonsense Mutation (SNP) | VAF 73/385 reads (19%) | catalogued as rs891583660; called by muse, mutect2, varscan2
- PCDHA5 | c.2048C>T p.A683V | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.001); catalogued as rs572635793, COSV65354845; called by muse, mutect2
- PPP6R2 | c.552C>T p.H184= | Splice Region (SNP) | VAF 64/260 reads (25%) | catalogued as rs544160556, COSV53292218; called by muse, mutect2, varscan2
- PTPRS | c.2836G>A p.V946I | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as rs778392508, COSV53623103; called by muse, mutect2, varscan2
- SCG3 | c.1056C>A p.S352R | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.316); catalogued as rs376589029; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4841G>T p.G1614V | Missense Mutation (SNP) | VAF 70/333 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHNAK | c.14263G>T p.A4755S | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- AMZ2 | c.681T>A p.S227R | Missense Mutation (SNP) | VAF 48/361 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AMZ2 | c.682G>T p.D228Y | Missense Mutation (SNP) | VAF 48/361 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ATP5MF | c.139+6A>G | Splice Region (SNP) | VAF 10/280 reads (4%) | called by muse, mutect2
- CHD8 | c.2884G>T p.D962Y (on ENST00000646647 / NM_001170629.2; = p.D683Y on NM_020920.4) | Missense Mutation (SNP) | VAF 178/451 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CRYAB | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 124/245 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- DNAI4 | c.2539T>A p.S847T | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by mutect2, varscan2
- F5 | c.2128C>G p.H710D | Missense Mutation (SNP) | VAF 180/414 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- FLG2 | c.4037G>T p.S1346I | Missense Mutation (SNP) | VAF 60/257 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- GHR | c.1274G>T p.C425F | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR33 | c.53G>T p.R18I | Missense Mutation (SNP) | VAF 187/547 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- KCNN3 | c.1247A>T p.Y416F | Missense Mutation (SNP) | VAF 85/455 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- L3MBTL3 | c.2127C>A p.S709R | Missense Mutation (SNP) | VAF 104/427 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MYOCD | c.2805G>T p.L935F | Missense Mutation (SNP) | VAF 126/530 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NID1 | c.525+1G>T p.X175_splice | Splice Site (SNP) | VAF 40/123 reads (33%) | called by muse, mutect2, varscan2
- PPL | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 64/223 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2
- RELN | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 49/274 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLITRK4 | c.2236C>A p.L746M | Missense Mutation (SNP) | VAF 5/104 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.019); called by muse, mutect2
- SMTN | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 92/366 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNFSF14 | c.331C>A p.P111T | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- CDH24 | c.2424C>A p.A808= | Silent (SNP) | VAF 129/328 reads (39%) | called by muse, mutect2, varscan2
- FAM83H | c.2916G>T p.L972= | Silent (SNP) | VAF 54/122 reads (44%) | called by muse, mutect2, varscan2
- FMNL1 | c.912C>T p.H304= | Silent (SNP) | VAF 72/330 reads (22%) | catalogued as rs141135994; called by muse, mutect2, varscan2
- FZD9 | c.1068C>T p.S356= | Silent (SNP) | VAF 57/224 reads (25%) | called by muse, mutect2, varscan2
- LRRC26 | c.12T>C p.P4= | Silent (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2
- MRGPRX4 | c.471G>A p.E157= | Silent (SNP) | VAF 98/215 reads (46%) | called by muse, mutect2, varscan2
- RHOBTB2 | c.159A>G p.V53= | Silent (SNP) | VAF 81/266 reads (30%) | catalogued as rs779450274; called by muse, mutect2, varscan2
- XPO6 | c.853C>A p.R285= | Silent (SNP) | VAF 78/308 reads (25%) | called by muse, varscan2
- BAG4 | c.*10G>T | 3'UTR (SNP) | VAF 45/119 reads (38%) | called by muse, mutect2, varscan2
- CACNA1A | c.*62G>T | 3'UTR (SNP) | VAF 44/95 reads (46%) | called by muse, mutect2, varscan2
- ERBB3 | c.613+43C>A | Intron (SNP) | VAF 31/113 reads (27%) | called by muse, mutect2, varscan2
- KAT5 | c.285+50del | Intron (DEL) | VAF 19/48 reads (40%) | called by mutect2, varscan2
- MUC19 | n.19816T>G | RNA (SNP) | VAF 70/244 reads (29%) | called by muse, mutect2, varscan2
- NCL | c.614-12C>T | Intron (SNP) | VAF 27/452 reads (6%) | called by muse, mutect2
- PLSCR3 | c.7+40dup | Intron (INS) | VAF 32/162 reads (20%) | catalogued as rs756551827; called by mutect2, varscan2
- SHISA5 | c.76+32C>T | Intron (SNP) | VAF 26/49 reads (53%) | called by mutect2, varscan2
- UROD | c.775-68A>G | Intron (SNP) | VAF 8/26 reads (31%) | called by muse, varscan2
